TCGA case TCGA-3H-AB3T — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3210027d-a9c7-4ebb-8497-e3705bed7e40

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Dead; Days to death: 414 days (1.1 years).

Diagnoses (3)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 79.2 years (28,925 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dasatinib; Days to treatment start: 35 days; Days to treatment end: 61 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 117 days; Days to treatment end: 152 days; Treatment dose: 60 Gy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 117 days; Days to treatment end: 152 days; Treatment dose: 45 Gy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 117 days; Days to treatment end: 152 days; Treatment dose: 50 Gy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Vorinostat; Days to treatment start: 321 days; Days to treatment end: 370 days (1.0 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pemetrexed.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Thorax, NOS. Age at diagnosis: 80.0 years (29,237 days); Days to diagnosis: 312 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Thorax, NOS. Age at diagnosis: 80.2 years (29,294 days); Days to diagnosis: 369 days (1.0 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 312 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 312 days.
- Day 369 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 369 days (1.0 years).
- Days to follow up: 414 days (1.1 years); Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 7.9; Timepoint: Prior to Treatment.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.3].

Exposures
- Exposure type: Asbestos; Exposure source: Occupational.
- Occupation type: Mining and Mineral Processing Plant Operators.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3H-AB3T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-3H-AB3T-01A-02-TS2: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
  Slide TCGA-3H-AB3T-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-3H-AB3T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: oil refinery.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Cisplatin, pemetrexed.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 414 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 414 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 312 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3H-AB3T-01A-11D-A39Q-01): tumor purity 0.44, ploidy 1.77, whole-genome doublings 0.
